Somatic mutation profile of tumor specimen TCGA-AP-A0LM-01A (aliquot TCGA-AP-A0LM-01A-11D-A122-09) from TCGA case TCGA-AP-A0LM, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 33.7 years (12,309 days).
Specimen TCGA-AP-A0LM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17d2af5e-e9a4-422b-9e3b-0fadb36edd60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0LM-10A (Blood Derived Normal), aliquot TCGA-AP-A0LM-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cd94ccd-a633-455f-b23c-86442aa82dc9

The open-access MAF lists 14,882 somatic variants for this specimen: 11,037 protein-altering or splice-affecting, 3,547 silent, 298 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9,842, Silent 3,547, Nonsense Mutation 866, Splice Site 159, Intron 135, Splice Region 105, RNA 78, Frame Shift Ins 32, 5'UTR 28, 3'UTR 23, Frame Shift Del 23, 5'Flank 18.

Variants (750 of 14,882; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVRL1 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28936401, CD050129, CM970049, COSV66361224; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALDH1A3 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs397514652, CM132959, COSV60900963; ClinVar: pathogenic; called by mutect2, varscan2
- ALX4 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 29/206 reads (14%) | catalogued as rs267606653, CM097094, COSV61326282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AR | c.1846C>T p.R616C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555990485, CM003407, CM107345, CM1312667, COSV65956439; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARSA | c.418del p.H140Ifs*8 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as rs745884435, CD085806, CM085251; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- ASPM | c.9319C>T p.R3107* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as rs199422187, CM092387, COSV54123750; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.4795C>T p.R1599* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as rs199422165, CM032843, COSV99661261; ClinVar: pathogenic; called by muse, varscan2
- ATP1A3 | c.2806G>A p.D936N (on ENST00000545399 / NM_001256214.2; = p.D923N on NM_152296.5) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); catalogued as rs267606670, CM094577, CM127594, COSV57487334; ClinVar: pathogenic; called by muse, varscan2
- BBS5 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1238632042, COSV54752696; ClinVar: likely pathogenic; called by mutect2, varscan2
- BMPR1A | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 18/107 reads (17%) | catalogued as rs764466442, CM014518, COSV64405911; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.1471C>T p.R491W | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852746, CM002241, COSV65808187; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1F | c.3886C>T p.R1296C | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557106557, CM055910, CM158325, COSV100544896, COSV59902931; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CACNA1F | c.1309+1G>A p.X437_splice | Splice Site (SNP) | VAF 21/75 reads (28%) | catalogued as rs782575860, COSV59904308; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CPA6 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 25/79 reads (32%) | catalogued as rs773734224, COSV52728383; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV62698994; called by mutect2, varscan2
- CUL7 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 57/225 reads (25%) | catalogued as rs746333044, COSV54816389; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CYP4F22 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs118203937, CM060278, COSV99513256; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDC | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 92/374 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs142110773, CM151311; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DST | c.4296+3962C>T | Intron (SNP) | VAF 20/118 reads (17%) | catalogued as rs577972555, COSV55012506; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EVC2 | c.2476C>T p.R826* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as rs548681312, CM098967, COSV60388652; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FAH | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | catalogued as rs769550316, CM960616, COSV55721276; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FANCA | c.2749C>T p.R917* | Nonsense Mutation (SNP) | VAF 11/96 reads (11%) | catalogued as rs1060501880, CM161205, COSV59796452; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by mutect2, varscan2
- FOXP3 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1557115786, CM086633, COSV66051279; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FUBP1 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 16/106 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408536007, COSV53927182; called by muse, mutect2, varscan2
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 26/94 reads (28%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, varscan2
- IYD | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918138, CM081315; ClinVar: pathogenic; called by muse, varscan2
- KCNQ1 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 36/135 reads (27%) | catalogued as rs17215500, CM057185, CM992171; ClinVar: pathogenic / benign / uncertain significance; called by muse, mutect2, varscan2
- KCNQ1 | c.1597C>T p.R533W | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs199472793, CM003453, COSV50107516; ClinVar: uncertain significance / not provided / pathogenic; called by muse, mutect2, varscan2
- KIF5A | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434442, CM042731, COSV99673680; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KLHL7 | c.1051C>T p.R351* (on ENST00000339077 / NM_001031710.3; = p.R303* on NM_018846.5) | Nonsense Mutation (SNP) | VAF 21/97 reads (22%) | catalogued as rs746612410, COSV59159623; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.7135C>T p.R2379* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as rs387907275, CM127144, COSV63285436; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LBR | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236962991, COSV55288753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LMNA | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs61094188, CM023951, COSV61541984; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- LPL | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs118204077, CM941054, COSV60929898; ClinVar: pathogenic; called by mutect2, varscan2
- LRP5 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 91/349 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs749683290, COSV53715133; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAGT1 | c.313C>T p.R105* (on ENST00000618282 / NM_001367916.1; = p.R137* on NM_032121.5) | Nonsense Mutation (SNP) | VAF 12/114 reads (11%) | catalogued as rs387906724, CM116461, COSV63781525; ClinVar: pathogenic; called by mutect2, varscan2
- MFN2 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 52/219 reads (24%) | catalogued as rs1057517987, CM050074, COSV52422272; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MOCS1 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893969, CM981300, COSV57933999; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as rs1553333707, CM1412053, COSV52274101; ClinVar: pathogenic; called by muse, varscan2
- MTHFR | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 25/161 reads (16%) | catalogued as rs986604359, COSV56739944; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NARS2 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367584549, COSV55250404; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NEFL | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1411999109, COSV55336921; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.647T>C p.L216P | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs199474756, CD1512842, CM000775, COSV62195135; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 97/389 reads (25%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OFD1 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 31/134 reads (23%) | catalogued as rs312262863, CM085622, COSV60795408; ClinVar: pathogenic; called by muse, varscan2
- OLFML2B | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as rs863224947, COSV54196092; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PAH | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs5030843, CM015340, CM890093; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.52); catalogued as rs1064793349, COSV55892795, COSV55921891; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PKD1 | c.12448C>T p.R4150C (on ENST00000262304 / NM_001009944.3; = p.R4149C on NM_000296.4) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1282668884, CM074420, COSV51915679; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLCB4 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397514481, CM123396, CM131144, COSV53800524; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PMM2 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs200503569, CM971223, COSV51631655; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- POGZ | c.1522C>T p.R508* | Nonsense Mutation (SNP) | VAF 11/82 reads (13%) | catalogued as rs1557901051, COSV55035225; ClinVar: pathogenic; called by muse, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLK | c.1284G>A p.A428= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs770984846, COSV54034895; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PSMD12 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 16/118 reads (14%) | catalogued as rs1114167442, COSV62065273; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PYGL | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113993980, CM078412, COSV99368859, COSV99369196; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PYGM | c.1456G>A p.G486S | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs926661627, COSV51216502; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAD51C | c.145+1G>A p.X49_splice | Splice Site (SNP) | VAF 20/71 reads (28%) | catalogued as rs757128712, CS102528, COSV53616245; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RFX6 | c.2596C>T p.R866* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as rs749827445, CM1512294, COSV100263268, COSV60584562; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RIMS1 | c.2459G>A p.R820H | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs121918302, CM034832; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- RNF43 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | hotspot (GDC flag); catalogued as rs786205215, CM154177, COSV68457376; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RPGRIP1L | c.3529C>T p.R1177* | Nonsense Mutation (SNP) | VAF 60/214 reads (28%) | catalogued as rs778533826, COSV50905890; ClinVar: pathogenic; called by muse, varscan2
- RPS6KA3 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as rs1555943484, CM981715, COSV65387679; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RUBCN | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as rs1114167292, COSV56365677; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- RUNX1 | c.530G>A p.R177Q (on ENST00000344691 / NM_001001890.3; = p.R204Q on NM_001754.5) | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1569061762, CM093278, COSV55866469, COSV55875660, COSV55875973; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- RYR1 | c.5989G>A p.E1997K | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1366464512, CM1513201, COSV100617244; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.14876G>A p.R4959Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs794728811, CM033018, COSV63658473; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SCN1A | c.3733C>T p.R1245* (on ENST00000303395 / NM_001202435.3; = p.R1234* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as rs727504136, CM031739, COSV57685915; ClinVar: pathogenic; called by muse, varscan2
- SCN2A | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1553567409, COSV51839806, COSV99330521; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SDHA | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); catalogued as rs397514541, CM163827, COSV53767867, COSV53772354; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SLC17A9 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs606231251, CM148568, COSV64846958; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC6A8 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs397515558, CM050327, COSV53472107; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPATA5 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as rs1446807404, COSV56775436; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SQSTM1 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 51/326 reads (16%) | catalogued as rs886039782, CM146303, COSV62434401, COSV62434714; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SRPX2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1556013503, COSV100883977, COSV65933194; ClinVar: likely pathogenic; called by muse, varscan2
- STAR | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs747169620, CM962754, COSV52417415; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TECRL | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773204795, COSV101168525, COSV67086765, COSV67089147; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TNXB | c.12961C>T p.R4321C (on ENST00000647633; = p.R4074C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/278 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587777682, CM136944, COSV64478400; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as rs900140738, COSV53196111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TREM2 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs104894002, CM033823; ClinVar: pathogenic; called by muse, varscan2
- TTN | c.48820C>T p.R16274* (on ENST00000591111; = p.R8850* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as rs753333359, COSV60032613; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTR | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs121918081, CM035091, CM920687, COSV52701442; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TWNK | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs80356542, CM074977, COSV99273325; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USH2A | c.14911C>T p.R4971* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as rs397517994, CM1110189, COSV56364393; ClinVar: pathogenic; called by mutect2, varscan2
- WAS | c.777+1G>A p.X259_splice | Splice Site (SNP) | VAF 22/220 reads (10%) | catalogued as rs1057517845, CS020216, CS961713, COSV64997624; ClinVar: pathogenic; called by muse, mutect2
- XDH | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as rs119460972, CM971597, COSV101052504, COSV65151007; ClinVar: pathogenic; called by muse, mutect2, varscan2
- XYLT1 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs587777367, CM142002, COSV54483543; ClinVar: pathogenic; called by mutect2, varscan2
- XYLT1 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 12/108 reads (11%) | catalogued as rs587777368, CM142003, COSV54485619; ClinVar: pathogenic; called by mutect2, varscan2
- ZAP70 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137853201, CM016238, COSV53852423; ClinVar: pathogenic; called by muse, varscan2
- ZNF142 | c.3775C>T p.R1259* (on ENST00000411696 / NM_001379660.1; = p.R1059* on NM_001105537.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as rs546151500, COSV101376903, COSV68743623; ClinVar: likely pathogenic; called by mutect2, varscan2
- A2M | c.1643C>T p.T548I | Missense Mutation (SNP) | VAF 70/291 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV59386004; called by muse, mutect2, varscan2
- A2M | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs369574498; called by muse, mutect2, varscan2
- A2ML1 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 27/107 reads (25%) | catalogued as rs759740387, COSV55290147; called by muse, mutect2, varscan2
- A2ML1 | c.1116G>T p.K372N | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV100229616; called by mutect2, varscan2
- A2ML1 | c.3296C>T p.A1099V | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751968824, COSV55290160; called by muse, mutect2, varscan2
- A4GALT | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.284); catalogued as rs1318461264, COSV50744353; called by muse, mutect2, varscan2
- A4GNT | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267599622, COSV52628852; called by muse, mutect2, varscan2
- AAAS | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as rs756366173, COSV52932873, COSV52933392; called by muse, mutect2, varscan2
- AAAS | c.239G>T p.C80F | Missense Mutation (SNP) | VAF 73/296 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV52932881; called by muse, mutect2, varscan2
- AADACL2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs760055575, COSV62929894; called by muse, mutect2, varscan2
- AADACL3 | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as COSV60198484; called by muse, mutect2, varscan2
- AADACL4 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs766773649, COSV100879518; called by muse, mutect2
- AAK1 | c.2741C>T p.A914V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV68643556; called by muse, varscan2
- AAK1 | c.2263G>C p.G755R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as COSV101276045; called by muse, mutect2, varscan2
- AAR2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as rs768628432, COSV57923893; called by muse, varscan2
- AARS1 | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs772849771, COSV55747281; called by muse, mutect2, varscan2
- AARS2 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 32/313 reads (10%) | catalogued as rs200450941, COSV55114605; called by muse, mutect2, varscan2
- AASDH | c.1514T>A p.L505H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52706337, COSV99221521; called by muse, mutect2, varscan2
- ABCA1 | c.6674G>T p.S2225I | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as COSV101037755; called by muse, mutect2
- ABCA1 | c.3272T>C p.M1091T | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as CM003222, COSV66065974; called by muse, varscan2
- ABCA1 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs745615655, COSV101037451, COSV66065988; called by muse, mutect2, varscan2
- ABCA10 | c.2206C>A p.L736I | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV52221612; called by muse, mutect2, varscan2
- ABCA10 | c.1880G>A p.R627K | Missense Mutation (SNP) | VAF 132/535 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV52221623; called by muse, mutect2, varscan2
- ABCA12 | c.3890G>A p.R1297Q (on ENST00000272895 / NM_173076.3; = p.R979Q on NM_015657.3) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.272); catalogued as rs747728722, COSV55956586; called by muse, mutect2, varscan2
- ABCA12 | c.3058G>A p.A1020T (on ENST00000272895 / NM_173076.3; = p.A702T on NM_015657.3) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55957911; called by muse, varscan2
- ABCA12 | c.1142T>C p.V381A (on ENST00000272895 / NM_173076.3; = p.V63A on NM_015657.3) | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV55957933; called by muse, mutect2, varscan2
- ABCA13 | c.1997G>T p.R666I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.263); catalogued as COSV70028052; called by muse, mutect2, varscan2
- ABCA13 | c.8340G>T p.E2780D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); catalogued as COSV71287209; called by mutect2, varscan2
- ABCA13 | c.9760G>T p.A3254S | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as COSV71287212; called by muse, mutect2, varscan2
- ABCA3 | c.4963C>T p.R1655C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs764785563, COSV57053091; called by muse, varscan2
- ABCA3 | c.3946G>A p.A1316T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs749616680, COSV57053100; called by muse, mutect2, varscan2
- ABCA4 | c.5196C>T p.I1732= | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as rs940382049, COSV64677960; called by muse, mutect2
- ABCA4 | c.4352C>T p.P1451L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs747928913, COSV64671065; called by mutect2, varscan2
- ABCA4 | c.2633C>T p.S878L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); catalogued as rs779160669, CM128916, COSV64673288; called by muse, varscan2
- ABCA5 | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV67016671; called by muse, mutect2, varscan2
- ABCA5 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs567168335, COSV67016676; called by muse, mutect2, varscan2
- ABCA6 | c.4825A>G p.K1609E | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV52638258; called by muse, mutect2, varscan2
- ABCA6 | c.3631G>A p.V1211I | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs751630890, COSV52638275; called by mutect2, varscan2
- ABCA6 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.022); catalogued as rs781249897, COSV52638284; called by muse, varscan2
- ABCA6 | c.2041+1G>T p.X681_splice | Splice Site (SNP) | VAF 12/38 reads (32%) | catalogued as COSV52638299; called by muse, varscan2
- ABCA8 | c.1926G>A p.A642= | Splice Region (SNP) | VAF 6/98 reads (6%) | catalogued as rs1008889375, COSV52196681; called by muse, mutect2
- ABCA8 | c.1456A>G p.T486A | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV52200497; called by muse, mutect2, varscan2
- ABCA9 | c.3068G>A p.R1023Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs770362206, COSV60624306; called by mutect2, varscan2
- ABCB1 | c.3083C>T p.P1028L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.07); catalogued as rs371977867, COSV99714689; called by muse, mutect2, varscan2
- ABCB1 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374940464, COSV55950385; called by muse, varscan2
- ABCB10 | c.1427C>A p.P476H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV60620996; called by muse, varscan2
- ABCB11 | c.247T>G p.F83V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV55589966; called by muse, mutect2, varscan2
- ABCB4 | c.271A>C p.N91H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as COSV55934834; called by muse, varscan2
- ABCB4 | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as COSV55934002; called by muse, mutect2, varscan2
- ABCC1 | c.2625G>T p.E875D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV60685203; called by muse, mutect2, varscan2
- ABCC1 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1264102348, COSV60685214; called by muse, mutect2, varscan2
- ABCC11 | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 17/58 reads (29%) | catalogued as rs759617112, COSV62322885; called by muse, mutect2, varscan2
- ABCC11 | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV62322891; called by muse, mutect2, varscan2
- ABCC12 | c.3901G>T p.D1301Y | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV60913631; called by muse, mutect2, varscan2
- ABCC12 | c.1749G>T p.K583N | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.139); catalogued as COSV60913639, COSV60915370; called by muse, mutect2, varscan2
- ABCC2 | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.266); catalogued as rs748245551, COSV64970648, COSV64970740; called by muse, mutect2, varscan2
- ABCC2 | c.1342A>C p.I448L | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64985955; called by muse, mutect2, varscan2
- ABCC3 | c.4142G>A p.R1381H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs182137402, COSV53321191; called by mutect2, varscan2
- ABCC5 | c.3035C>T p.P1012L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55589583; called by muse, varscan2
- ABCC6 | c.1914G>A p.W638* | Nonsense Mutation (SNP) | VAF 18/93 reads (19%) | catalogued as COSV52743609; called by muse, mutect2, varscan2
- ABCC8 | c.4399C>T p.P1467S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV56849877; called by muse, mutect2, varscan2
- ABCC8 | c.1507C>T p.L503F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1027198360, COSV56849905; called by muse, mutect2, varscan2
- ABCC9 | c.2080C>T p.R694* | Nonsense Mutation (SNP) | VAF 37/122 reads (30%) | catalogued as rs1194330942, COSV53966814; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.1483A>G p.T495A | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99687579; called by muse, mutect2
- ABCD1 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204814114, CD951566, CM158477, COSV54384506; called by muse, varscan2
- ABCD3 | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64643078; called by muse, mutect2, varscan2
- ABCE1 | c.404A>T p.D135V | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV56847077; called by muse, mutect2, varscan2
- ABCG1 | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as rs1406129471, COSV59203758; called by muse, mutect2, varscan2
- ABCG4 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs201193587, COSV56643434; called by muse, mutect2, varscan2
- ABCG4 | c.1786C>T p.R596C | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.208); catalogued as rs765658479, COSV56643444, COSV56644542; called by muse, mutect2, varscan2
- ABCG8 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.21); catalogued as rs746141470, COSV55393018; called by muse, mutect2, varscan2
- ABHD1 | c.1189C>A p.L397I | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.287); catalogued as COSV53205917; called by muse, mutect2, varscan2
- ABHD10 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs779860005, COSV56325045; called by muse, varscan2
- ABHD12B | c.425T>G p.I142S (on ENST00000337334 / NM_001206673.2; = p.I65S on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV100485867; called by muse, mutect2
- ABHD4 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs142817719; called by muse, mutect2, varscan2
- ABHD6 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55908553; called by muse, mutect2, varscan2
- ABI2 | c.1040C>A p.P347H (on ENST00000295851 / NM_001375719.1; = p.P280H on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV99651830; called by muse, mutect2
- ABI3BP | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs553697655, COSV52528518; called by muse, mutect2, varscan2
- ABL2 | c.859G>T p.D287Y (on ENST00000502732 / NM_007314.4; = p.D272Y on NM_005158.5) | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61013612; called by muse, mutect2, varscan2
- ABL2 | c.670A>C p.T224P (on ENST00000502732 / NM_007314.4; = p.T209P on NM_005158.5) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV61013641; called by muse, mutect2, varscan2
- ABLIM2 | c.1343G>A p.G448E (on ENST00000341937 / NM_001130084.2; = p.G396E on NM_032432.5) | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV56403833; called by muse, mutect2, varscan2
- ABLIM2 | c.750G>T p.E250D | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56403856; called by muse, varscan2
- ABR | c.550T>C p.Y184H (on ENST00000302538 / NM_021962.5; = p.Y147H on NM_001092.5) | Missense Mutation (SNP) | VAF 38/405 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV99348762; called by muse, mutect2
- ABRAXAS1 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV55029587; called by muse, varscan2
- ABRAXAS1 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 52/444 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV58948342; called by muse, mutect2, varscan2
- ABRAXAS2 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV53716696; called by muse, mutect2, varscan2
- ABT1 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.33); catalogued as COSV51291197; called by muse, mutect2, varscan2
- ABTB1 | c.460G>A p.V154M (on ENST00000232744 / NM_172027.3; = p.V12M on NM_032548.3) | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs775900330, COSV51741071, COSV51742016; called by muse, mutect2, varscan2
- ABTB2 | c.2276C>T p.S759L | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs1173284303, COSV54387774; called by muse, mutect2, varscan2
- ABTB2 | c.2038G>A p.V680M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1287610653, COSV54387790; called by muse, mutect2
- AC004593.2 | c.1094G>T p.R365I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.642); catalogued as COSV56091646; called by muse, mutect2, varscan2
- AC005324.2 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 73/486 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.023); catalogued as rs375375292, COSV60886616; called by muse, mutect2, varscan2
- AC005324.2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.49); catalogued as rs567631499, COSV60886622; called by muse, mutect2
- AC005833.1 | c.1466A>G p.D489G | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT deleterious, low confidence (0.04); catalogued as COSV52897185; called by muse, mutect2, varscan2
- AC006059.2 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); catalogued as COSV59606751; called by muse, varscan2
- AC008397.2 | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.05); catalogued as COSV62747566; called by muse, mutect2, varscan2
- AC013489.1 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); catalogued as rs201071368; called by muse, mutect2, varscan2
- AC026464.6 | c.368A>G p.E123G | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99652183; called by muse, mutect2, varscan2
- AC097636.1 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs369862122; called by muse, mutect2, varscan2
- AC098582.1 | c.2116G>T p.D706Y | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52019827; called by muse, mutect2, varscan2
- AC126283.2 | c.995G>T p.R332I | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV67098041, COSV67098536; called by muse, mutect2, varscan2
- AC132217.2 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100324299; called by muse, varscan2
- AC132217.2 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); catalogued as rs368323611, COSV100324300; called by muse, varscan2
- AC134980.2 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 29/181 reads (16%) | catalogued as rs202083008, COSV60907556; called by muse, mutect2, varscan2
- ACAA1 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs934594058, COSV57173838; called by muse, mutect2, varscan2
- ACACB | c.2458G>A p.G820R | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as rs550603462, COSV58133821; called by muse, varscan2
- ACAD10 | c.2093C>T p.S698F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.368); catalogued as COSV58153637; called by muse, mutect2, varscan2
- ACAD10 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as rs759706100, COSV58153830; called by muse, mutect2, varscan2
- ACAD11 | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as COSV53895908; called by muse, mutect2, varscan2
- ACADL | c.1118C>A p.S373Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs766903314, COSV52053249; called by muse, varscan2
- ACADL | c.941T>C p.V314A | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV52053260; called by muse, mutect2, varscan2
- ACADM | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 114/504 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769906625, COSV63720304; called by muse, mutect2, varscan2
- ACADSB | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs746639403, COSV62550657; called by muse, mutect2, varscan2
- ACADVL | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451455641, COSV50035561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACADVL | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 110/462 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767849841, COSV50035667; called by muse, mutect2, varscan2
- ACAN | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1293500351, COSV61359932; called by muse, mutect2, varscan2
- ACAN | c.5369C>A p.S1790Y | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61359937; called by muse, mutect2, varscan2
- ACAN | c.6049G>T p.E2017* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100719421, COSV61368457; called by muse, mutect2
- ACAN | c.6676A>G p.T2226A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.372); catalogued as COSV61359943; called by muse, mutect2, varscan2
- ACAP2 | c.2232G>T p.Q744H | Missense Mutation (SNP) | VAF 59/266 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as COSV58751711; called by muse, mutect2, varscan2
- ACAP2 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV100462881; called by muse, mutect2, varscan2
- ACAP2 | c.274A>G p.N92D | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.597); catalogued as COSV58751725, COSV58753867; called by muse, mutect2
- ACBD3 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1558121720, COSV64730309; called by muse, mutect2, varscan2
- ACBD3 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as rs781141478, COSV64730313; called by muse, mutect2, varscan2
- ACBD5 | c.1076G>A p.G359E (on ENST00000375888 / NM_001352568.1; = p.G350E on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as COSV65519087; called by muse, mutect2, varscan2
- ACCS | c.234G>T p.E78D | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV55458124; called by muse, mutect2, varscan2
- ACCSL | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66581140; called by muse, mutect2, varscan2
- ACE | c.440T>C p.M147T | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773425152, COSV52020166; called by muse, varscan2
- ACE | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs371544905, COSV99327658; called by muse, mutect2, varscan2
- ACE | c.2477G>T p.R826M | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV99327844; called by muse, mutect2
- ACE2 | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.658); catalogued as COSV53024842; called by muse, mutect2, varscan2
- ACER3 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 26/126 reads (21%) | catalogued as rs782329790, COSV53598670; called by muse, mutect2, varscan2
- ACKR2 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs754472756, COSV56177756; called by muse, mutect2, varscan2
- ACLY | c.3125C>T p.S1042F | Missense Mutation (SNP) | VAF 81/363 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.58); catalogued as COSV59861939; called by muse, mutect2, varscan2
- ACLY | c.2912T>C p.M971T | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.322); catalogued as COSV61250551; called by muse, mutect2, varscan2
- ACO1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV59379607; called by muse, mutect2, varscan2
- ACO1 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV59379622; called by muse, mutect2, varscan2
- ACO1 | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748369667, COSV59379324; called by muse, mutect2, varscan2
- ACO1 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs112153542; called by muse, mutect2, varscan2
- ACOT11 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs776686227, COSV56363969; called by mutect2, varscan2
- ACOT12 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs201083196, COSV56894684; called by mutect2, varscan2
- ACOT2 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 187/742 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762096982, COSV53150249; called by muse, varscan2
- ACOT7 | c.1114C>T p.R372* (on ENST00000377855 / NM_181864.3; = p.R362* on NM_007274.4) | Nonsense Mutation (SNP) | VAF 16/139 reads (12%) | catalogued as rs745847219, COSV64113029; called by mutect2, varscan2
- ACOT9 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV60537585; called by muse, mutect2, varscan2
- ACOX1 | c.1766A>G p.N589S | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV99504063; called by muse, mutect2
- ACOX1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs780812320, COSV53131399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACP7 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV58699241; called by muse, mutect2, varscan2
- ACR | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs752153585, COSV53360939, COSV53361660; called by muse, mutect2, varscan2
- ACSBG1 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs763765195, COSV51905663; called by muse, mutect2, varscan2
- ACSF3 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); catalogued as rs1407341761, COSV58078263; called by muse, mutect2, varscan2
- ACSL3 | c.366A>C p.K122N | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62481998; called by muse, mutect2, varscan2
- ACSL4 | c.559G>A p.E187K (on ENST00000340800 / NM_022977.2; = p.E146K on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.388); catalogued as rs367728271, COSV61614238; called by muse, mutect2, varscan2
- ACSM1 | c.195G>A p.E65= | Splice Region (SNP) | VAF 14/100 reads (14%) | catalogued as COSV54635444; called by muse, mutect2, varscan2
- ACSM2A | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs750848675, COSV54584481; called by mutect2, varscan2
- ACSM2B | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61657715; called by muse, mutect2, varscan2
- ACSM2B | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV61657732; called by muse, mutect2, varscan2
- ACSM3 | c.1661A>C p.K554T | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55501228; called by muse, mutect2, varscan2
- ACSM5 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as rs543757679, COSV59371141; called by mutect2, varscan2
- ACSM5 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs141553052; called by muse, varscan2
- ACTC1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.959); catalogued as rs1555418793, COSV51758368; ClinVar: uncertain significance; called by muse, varscan2
- ACTC1 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV51758909, COSV51759438; called by muse, varscan2
- ACTC1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.636); catalogued as COSV51758927, COSV51762255; called by muse, varscan2
- ACTC1 | c.18G>T p.E6D | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.139); catalogued as COSV99292213; called by muse, mutect2
- ACTL6B | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV50514392, COSV50514775; called by muse, mutect2, varscan2
- ACTL8 | c.562C>A p.L188I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as rs760648218, COSV64861319; called by mutect2, varscan2
- ACTL8 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as COSV64861324; called by muse, mutect2, varscan2
- ACTN3 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763136343, COSV72207580; called by muse, mutect2, varscan2
- ACTN3 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 65/274 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs774285672, COSV72207581; called by muse, mutect2, varscan2
- ACTN3 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770542513, COSV72207582; called by muse, mutect2, varscan2
- ACTN3 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs760434035, COSV59748536; called by muse, mutect2, varscan2
- ACTR8 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 45/155 reads (29%) | catalogued as rs762405003, COSV51636231; called by muse, mutect2, varscan2
- ACTRT1 | c.452T>A p.V151D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV64419308; called by muse, varscan2
- ACVR1B | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57776052; called by muse, mutect2, varscan2
- ACVR2A | c.25T>C p.F9L | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV54021820; called by muse, mutect2, varscan2
- ACVR2A | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs770920471, COSV54021831; called by muse, mutect2, varscan2
- ACVR2B | c.1308G>T p.M436I | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100754442; called by muse, mutect2
- ACVRL1 | c.1050C>T p.G350= | Splice Region (SNP) | VAF 6/48 reads (13%) | catalogued as COSV101187761; called by muse, mutect2
- ADA2 | c.917G>A p.R306Q (on ENST00000262607; = p.R65Q on NM_177405.3) | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs768927379, COSV52830417; called by muse, mutect2, varscan2
- ADAD1 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs766007013, COSV56643265; called by muse, mutect2, varscan2
- ADAL | c.355A>C p.K119Q | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV67500469; called by muse, mutect2, varscan2
- ADAM10 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53052234, COSV99546847; called by muse, mutect2
- ADAM17 | c.250A>C p.T84P | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.723); catalogued as COSV60398617; called by muse, mutect2, varscan2
- ADAM19 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs147812090, COSV57429128; called by muse, mutect2, varscan2
- ADAM2 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55861699; called by muse, mutect2, varscan2
- ADAM21 | c.793A>C p.N265H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50792468, COSV50805951; called by muse, mutect2, varscan2
- ADAM22 | c.2193T>C p.G731= | Splice Region (SNP) | VAF 21/75 reads (28%) | catalogued as COSV55976110; called by muse, mutect2, varscan2
- ADAM23 | c.378A>C p.E126D | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52214482; called by muse, mutect2, varscan2
- ADAM28 | c.822G>T p.E274D | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.762); catalogued as rs1392638105, COSV56099330, COSV56100596; called by muse, varscan2
- ADAM29 | c.621T>A p.D207E | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as COSV63663301; called by muse, mutect2, varscan2
- ADAM29 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs746641739, COSV63663321; called by muse, varscan2
- ADAM30 | c.1516C>A p.Q506K | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV101024004; called by muse, mutect2
- ADAM30 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as COSV65561014, COSV65562307; called by muse, mutect2, varscan2
- ADAM7 | c.1490G>A p.G497D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51539385; called by muse, varscan2
- ADAM7 | c.2153G>A p.G718D | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.113); catalogued as rs946930666, COSV51539401; called by muse, varscan2
- ADAM8 | c.1442G>A p.G481D | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101291759; called by muse, mutect2, varscan2
- ADAM9 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs1205964041, COSV65946572, COSV65946664, COSV65946805; called by muse, mutect2, varscan2
- ADAMTS1 | c.2035G>T p.D679Y | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53170145; called by muse, mutect2, varscan2
- ADAMTS1 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370561058; called by muse, mutect2, varscan2
- ADAMTS13 | c.330C>T p.I110= | Splice Region (SNP) | VAF 10/82 reads (12%) | catalogued as rs142107133; called by muse, mutect2, varscan2
- ADAMTS13 | c.3740G>A p.R1247Q | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs782197792, COSV52469811; called by muse, mutect2, varscan2
- ADAMTS13 | c.4263G>T p.W1421C | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.237); catalogued as COSV52469817; called by muse, mutect2, varscan2
- ADAMTS15 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV54505169; called by muse, mutect2, varscan2
- ADAMTS16 | c.347G>A p.S116N | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1423929242, COSV56987910; called by muse, mutect2, varscan2
- ADAMTS17 | c.2780C>T p.A927V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs756721876, COSV99171736; called by mutect2, varscan2
- ADAMTS17 | c.477G>T p.E159D | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.683); catalogued as COSV51479554; called by muse, mutect2, varscan2
- ADAMTS19 | c.1484G>A p.G495D | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50745661; called by muse, varscan2
- ADAMTS19 | c.1823G>T p.R608I | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.207); catalogued as rs1007394270, COSV50745702; called by muse, mutect2, varscan2
- ADAMTS19 | c.2204C>A p.P735H | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV50745735; called by muse, varscan2
- ADAMTS19 | c.2390T>A p.I797N | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV50745801; called by muse, mutect2, varscan2
- ADAMTS2 | c.2822G>A p.R941H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs771394684, COSV52373858; called by muse, mutect2, varscan2
- ADAMTS20 | c.5323C>T p.P1775S | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV67130829; called by muse, mutect2, varscan2
- ADAMTS20 | c.4162C>A p.P1388T | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as COSV67130834, COSV67137841; called by muse, mutect2, varscan2
- ADAMTS20 | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 54/506 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs540412377, COSV67130839; called by muse, mutect2, varscan2
- ADAMTS3 | c.3439G>A p.V1147I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs759487867, COSV54390590; called by muse, varscan2
- ADAMTS3 | c.3395G>T p.R1132M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.169); catalogued as COSV99712299; called by muse, varscan2
- ADAMTS3 | c.2742G>A p.W914* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99712300; called by muse, mutect2, varscan2
- ADAMTS3 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.626); catalogued as rs1223091287, COSV54390611; called by muse, mutect2, varscan2
- ADAMTS3 | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.167); catalogued as COSV54390620; called by muse, varscan2
- ADAMTS4 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1243925734, COSV63487580; called by muse, mutect2, varscan2
- ADAMTS6 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66859397; called by muse, mutect2, varscan2
- ADAMTS7 | c.2726G>A p.R909H | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs547944533, COSV101183308; called by muse, mutect2
- ADAMTS9 | c.2587G>A p.D863N | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.44); catalogued as rs375095054; called by mutect2, varscan2
- ADAMTS9 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV55780424; called by muse, mutect2, varscan2
- ADAMTSL1 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs267602193, COSV52815026; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs554272440, COSV65891963; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2491C>A p.L831M | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV65891966; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4175C>T p.P1392L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs368567865; called by muse, mutect2, varscan2
- ADAMTSL3 | c.439T>C p.Y147H | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); catalogued as COSV99721612; called by muse, mutect2
- ADAMTSL3 | c.3848C>T p.A1283V | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV99721619; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs185549053; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1939C>T p.R647W | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs763490075, COSV54999409; called by mutect2, varscan2
- ADAMTSL4 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs746430948, COSV54999417; called by muse, mutect2, varscan2
- ADAP2 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 43/252 reads (17%) | catalogued as rs199866282, COSV58294906; called by muse, mutect2, varscan2
- ADAR | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs760911897, COSV52714849; called by muse, mutect2, varscan2
- ADARB1 | c.2065C>T p.R689C (on ENST00000360697 / NM_001346687.2; = p.R649C on NM_001112.4) | Missense Mutation (SNP) | VAF 15/311 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); catalogued as COSV62345289; called by muse, mutect2
- ADAT2 | c.504G>T p.K168N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52794261; called by muse, varscan2
- ADAT2 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV52794274; called by muse, mutect2, varscan2
- ADCK5 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782231379, COSV58233472; called by muse, mutect2, varscan2
- ADCY1 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs1562677845, COSV52029792, COSV52033448; called by muse, mutect2
- ADCY1 | c.1148+1G>A p.X383_splice | Splice Site (SNP) | VAF 14/50 reads (28%) | catalogued as rs775475672, COSV52033392, COSV52034912; called by muse, varscan2
- ADCY1 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as rs536487311, COSV52032873; called by muse, varscan2
- ADCY1 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.217); catalogued as COSV52034039; called by muse, mutect2, varscan2
- ADCY1 | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs781058119, COSV52032726; called by muse, mutect2, varscan2
- ADCY1 | c.3022C>T p.R1008W | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52030467; called by muse, mutect2
- ADCY10 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.478); catalogued as rs774828588, COSV63240542; called by muse, mutect2, varscan2
- ADCY2 | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 4/45 reads (9%) | catalogued as COSV57861118; called by mutect2, varscan2
- ADCY2 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as rs1390769718, COSV57863600; called by muse, mutect2, varscan2
- ADCY2 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV57870684; called by muse, mutect2, varscan2
- ADCY3 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs752799012, COSV53167226; called by muse, mutect2, varscan2
- ADCY4 | c.3203G>A p.R1068Q | Missense Mutation (SNP) | VAF 34/556 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs1378408153, COSV60253710; called by muse, mutect2
- ADCY5 | c.3313G>A p.A1105T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1451387994, COSV59197369; called by muse, mutect2, varscan2
- ADCY8 | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV53907314, COSV53907324; called by mutect2, varscan2
- ADCY9 | c.3188G>T p.S1063I | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53574805; called by muse, varscan2
- ADCY9 | c.2792C>T p.P931L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53574819; called by muse, mutect2, varscan2
- ADCY9 | c.1110G>T p.K370N | Missense Mutation (SNP) | VAF 109/432 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as COSV53574830; called by muse, mutect2, varscan2
- ADD1 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.412); catalogued as COSV53268802; called by muse, mutect2, varscan2
- ADD1 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.166); catalogued as rs957911196, COSV99297169; called by muse, mutect2
- ADD2 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as COSV52460452; called by muse, mutect2, varscan2
- ADD2 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52460736; called by muse, varscan2
- ADD3 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs767558945, COSV53321083; called by muse, varscan2
- ADD3 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.271); catalogued as COSV53322127; called by mutect2, varscan2
- ADGRA1 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as rs1410855229, COSV66925501; called by muse, mutect2
- ADGRA3 | c.1029G>T p.E343D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV51562713; called by muse, mutect2, varscan2
- ADGRB1 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60094577; called by muse, mutect2, varscan2
- ADGRB1 | c.3775C>A p.P1259T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as COSV60096093, COSV60097373; called by muse, mutect2, varscan2
- ADGRB2 | c.3958G>A p.E1320K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs1430172582, COSV57073355; called by muse, mutect2
- ADGRB2 | c.2623G>A p.A875T | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV57073364; called by muse, mutect2, varscan2
- ADGRB2 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.459); catalogued as rs201601920; called by muse, mutect2, varscan2
- ADGRB3 | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.558); catalogued as rs1462357252, COSV65393599, COSV65416438; called by muse, mutect2, varscan2
- ADGRB3 | c.2025G>A p.M675I | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as rs778842222, COSV65393603; called by muse, mutect2, varscan2
- ADGRD1 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); catalogued as COSV55444456; called by muse, mutect2, varscan2
- ADGRD1 | c.353C>A p.S118Y | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as COSV55444465; called by muse, mutect2, varscan2
- ADGRE1 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs1331203412, COSV51674629; called by muse, mutect2, varscan2
- ADGRE5 | c.822G>A p.T274= (on ENST00000242786 / NM_078481.4; = p.T181= on NM_001784.5) | Splice Region (SNP) | VAF 44/186 reads (24%) | catalogued as rs1267717952, COSV54410285; called by muse, mutect2, varscan2
- ADGRE5 | c.1016G>T p.R339M (on ENST00000242786 / NM_078481.4; = p.R246M on NM_001784.5) | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54410296; called by muse, mutect2, varscan2
- ADGRE5 | c.1225A>G p.T409A (on ENST00000242786 / NM_078481.4; = p.T316A on NM_001784.5) | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV54410312; called by muse, mutect2, varscan2
- ADGRE5 | c.1531G>A p.E511K (on ENST00000242786 / NM_078481.4; = p.E418K on NM_001784.5) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.078); catalogued as rs748373111, COSV54391440; called by muse, mutect2, varscan2
- ADGRG3 | c.845T>G p.F282C | Missense Mutation (SNP) | VAF 61/258 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59650994; called by muse, mutect2, varscan2
- ADGRG4 | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV54955274; called by muse, mutect2, varscan2
- ADGRG4 | c.4508C>A p.S1503Y | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV54955283; called by mutect2, varscan2
- ADGRG4 | c.5156C>A p.S1719Y | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV99797242; called by muse, mutect2, varscan2
- ADGRG4 | c.5558C>T p.S1853F | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV54955296; called by muse, varscan2
- ADGRG4 | c.6176T>G p.L2059R | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV54955315; called by muse, mutect2, varscan2
- ADGRG4 | c.7184A>G p.Y2395C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV54957778, COSV99797248; called by muse, mutect2, varscan2
- ADGRG4 | c.7647G>T p.K2549N | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1286224125, COSV54955324; called by muse, mutect2, varscan2
- ADGRG5 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 16/159 reads (10%) | catalogued as COSV61083232, COSV61084307; called by muse, mutect2
- ADGRG6 | c.39G>A p.W13* | Nonsense Mutation (SNP) | VAF 37/275 reads (13%) | catalogued as COSV51591391; called by muse, varscan2
- ADGRG6 | c.735T>G p.I245M | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.793); catalogued as COSV51591417; called by muse, varscan2
- ADGRG7 | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs144717099, COSV99841095; called by muse, mutect2, varscan2
- ADGRG7 | c.2098G>A p.V700I | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV56296155; called by muse, mutect2, varscan2
- ADGRL1 | c.3533G>A p.R1178Q (on ENST00000340736 / NM_001008701.3; = p.R1173Q on NM_014921.5) | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.277); catalogued as rs145585934; called by muse, mutect2, varscan2
- ADGRL1 | c.2884C>T p.R962C (on ENST00000340736 / NM_001008701.3; = p.R957C on NM_014921.5) | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs150820451; called by muse, mutect2, varscan2
- ADGRL1 | c.2743G>A p.D915N (on ENST00000340736 / NM_001008701.3; = p.D910N on NM_014921.5) | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.244); catalogued as rs370012631; called by muse, varscan2
- ADGRL1 | c.2582C>T p.S861L (on ENST00000340736 / NM_001008701.3; = p.S856L on NM_014921.5) | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.227); catalogued as rs781100862, COSV61564578; called by muse, varscan2
- ADGRL1 | c.1852A>G p.K618E (on ENST00000340736 / NM_001008701.3; = p.K613E on NM_014921.5) | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV61564585; called by muse, mutect2
- ADGRL2 | c.2747T>G p.L916R (on ENST00000370717 / NM_001366005.1; = p.L903R on NM_012302.4) | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV54665565; called by muse, varscan2
- ADGRL3 | c.3763G>T p.E1255* (on ENST00000506720 / NM_001322402.2; = p.E1187* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV72230212, COSV72230468; called by muse, mutect2, varscan2
- ADGRL4 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs368339256; called by mutect2, varscan2
- ADH1A | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs781090973, COSV52924876; called by muse, mutect2, varscan2
- ADH1C | c.949G>T p.G317* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as COSV72463453; called by muse, mutect2, varscan2
- ADH7 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52922416, COSV52922927; called by muse, mutect2, varscan2
- ADHFE1 | c.809C>A p.P270H | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99398251; called by mutect2, varscan2
- ADIPOR2 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV63946211; called by muse, varscan2
- ADIPOR2 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs1407413750, COSV63945704; called by muse, mutect2, varscan2
- ADNP | c.526C>A p.L176I | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV62425202; called by muse, mutect2, varscan2
- ADNP2 | c.1253T>C p.V418A | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV51538468; called by muse, mutect2, varscan2
- ADNP2 | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs377757808; called by muse, mutect2, varscan2
- ADORA2A | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs939477540, COSV58379159; called by muse, mutect2
- ADORA2A | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV58378834; called by muse, mutect2, varscan2
- ADORA3 | c.602T>G p.F201C | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99598925; called by muse, mutect2
- ADPRHL1 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.659); catalogued as rs375108772; called by muse, mutect2, varscan2
- ADRA1A | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52363106; called by mutect2, varscan2
- ADRB2 | c.570C>A p.C190* | Nonsense Mutation (SNP) | VAF 69/431 reads (16%) | catalogued as COSV60005470; called by muse, mutect2, varscan2
- ADSS1 | c.541C>A p.R181S | Missense Mutation (SNP) | VAF 37/322 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100272453; called by muse, mutect2, varscan2
- AEBP1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 41/363 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV56256086, COSV56257213; called by muse, mutect2, varscan2
- AEBP2 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.978); catalogued as rs1267642910, COSV99858097; called by muse, mutect2, varscan2
- AFAP1 | c.2002T>C p.S668P | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV61795450; called by muse, mutect2, varscan2
- AFAP1L1 | c.1423C>T p.R475* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as rs1260509573, COSV57045054; called by muse, mutect2, varscan2
- AFAP1L2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as rs887113324, COSV58414402; called by muse, mutect2, varscan2
- AFF1 | c.3513A>T p.E1171D | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV57119517; called by muse, mutect2, varscan2
- AFF2 | c.33C>A p.D11E | Missense Mutation (SNP) | VAF 102/482 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV60663915; called by muse, varscan2
- AFF2 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV60663924; called by muse, mutect2, varscan2
- AFF2 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 38/119 reads (32%) | catalogued as COSV53988097; called by muse, mutect2, varscan2
- AFF3 | c.3473C>T p.A1158V | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57853115; called by muse, mutect2, varscan2
- AFF3 | c.2633C>T p.S878L | Missense Mutation (SNP) | VAF 59/298 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs557360368, COSV57853126; called by muse, varscan2
- AFF3 | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV100420291; called by muse, mutect2, varscan2
- AFG3L2 | c.1864T>G p.L622V | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.412); catalogued as COSV52314255; called by mutect2, varscan2
- AFM | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as rs771719904, COSV56919283, COSV56920023; called by muse, mutect2, varscan2
- AFM | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.37); catalogued as rs151113361, COSV56919198, COSV99888811; called by muse, mutect2
- AFMID | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs769495118, COSV59976003; called by mutect2, varscan2
- AFP | c.1578C>A p.F526L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.996); catalogued as COSV56925018; called by muse, mutect2, varscan2
- AGAP2 | c.1401G>T p.K467N (on ENST00000547588 / NM_001122772.2; = p.K131N on NM_014770.4) | Missense Mutation (SNP) | VAF 38/377 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV57727989; called by muse, mutect2, varscan2
- AGAP2 | c.1273C>T p.R425* (on ENST00000547588 / NM_001122772.2; = p.R89* on NM_014770.4) | Nonsense Mutation (SNP) | VAF 16/218 reads (7%) | catalogued as rs1172088100, COSV99224470; called by muse, mutect2
- AGAP4 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1347036003; called by muse, mutect2
- AGAP6 | c.1633C>T p.R545C (on ENST00000374056 / NM_001365867.1; = p.R568C on NM_001077665.2) | Missense Mutation (SNP) | VAF 59/272 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs782697526, COSV65017635; called by muse, varscan2
- AGAP6 | c.1708C>T p.R570W (on ENST00000374056 / NM_001365867.1; = p.R593W on NM_001077665.2) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs782163616; called by muse, varscan2
- AGBL1 | c.1088A>C p.E363A | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV101224376; called by muse, mutect2, varscan2
- AGBL1 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV66857190; called by muse, mutect2, varscan2
- AGBL1 | c.2674C>T p.R892* | Nonsense Mutation (SNP) | VAF 28/131 reads (21%) | catalogued as rs371874943, COSV66857185; called by muse, mutect2, varscan2
- AGBL2 | c.1523T>C p.V508A | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV54091647; called by muse, mutect2, varscan2
- AGBL5 | c.793T>G p.F265V | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV59936471; called by muse, mutect2, varscan2
- AGFG1 | c.749G>T p.S250I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1176944114, COSV59511711; called by muse, mutect2
- AGFG2 | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53545039; called by muse, mutect2
- AGGF1 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 38/369 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57228910; called by muse, mutect2, varscan2
- AGGF1 | c.1740G>T p.K580N | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57228919; called by muse, mutect2, varscan2
- AGL | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 58/481 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV54052237; called by muse, mutect2, varscan2
- AGL | c.2868T>G p.F956L | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54052248; called by muse, mutect2, varscan2
- AGMO | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV61109625; called by muse, mutect2, varscan2
- AGMO | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs552347223, COSV61111763; called by muse, varscan2
- AGO1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs773153331, COSV64595181; called by muse, mutect2, varscan2
- AGO1 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs745615692, COSV64595185; called by muse, varscan2
- AGO1 | c.1915G>T p.D639Y | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100940949; called by muse, mutect2
- AGO1 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64595188; called by muse, mutect2, varscan2
- AGO2 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs935259974, COSV55047128; called by muse, mutect2, varscan2
- AGPAT5 | c.1063C>T p.L355F | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs141365320; called by muse, mutect2, varscan2
- AGPS | c.350+1G>A p.X117_splice | Splice Site (SNP) | VAF 10/106 reads (9%) | catalogued as COSV99931784; called by muse, mutect2, varscan2
- AGRN | c.3103G>A p.V1035M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs756015484, COSV65069371; called by muse, mutect2, varscan2
- AGRP | c.67A>G p.M23V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV52097590; called by muse, mutect2
- AGTPBP1 | c.3503+2T>C p.X1168_splice (on ENST00000357081 / NM_001330701.2; = p.X1128_splice on NM_015239.2) | Splice Site (SNP) | VAF 60/242 reads (25%) | catalogued as COSV61271281; called by muse, mutect2, varscan2
- AGTPBP1 | c.1204G>A p.D402N (on ENST00000357081 / NM_001330701.2; = p.D362N on NM_015239.2) | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61271291; called by muse, mutect2, varscan2
- AGTR2 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV64157173; called by muse, mutect2
- AGXT2 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746146731, COSV51483571; called by muse, varscan2
- AGXT2 | c.495C>A p.F165L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as rs1554036019, COSV51486089; called by mutect2, varscan2
- AGXT2 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs754018269, COSV51486117; called by muse, mutect2, varscan2
- AHCTF1 | c.4537C>A p.L1513I (on ENST00000366508; = p.L1487I on NM_015446.5) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV58249469; called by muse, mutect2, varscan2
- AHCTF1 | c.3365C>A p.S1122Y (on ENST00000366508; = p.S1096Y on NM_015446.5) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV58249476; called by muse, mutect2, varscan2
- AHCTF1 | c.3187C>T p.R1063* (on ENST00000366508; = p.R1037* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100404532; called by muse, varscan2
- AHCTF1 | c.2499C>A p.F833L (on ENST00000366508; = p.F807L on NM_015446.5) | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100403425, COSV58249484; called by muse, mutect2, varscan2
- AHCYL1 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63208599; called by muse, varscan2
- AHI1 | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 113/416 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs551136002, COSV55627183; called by muse, mutect2, varscan2
- AHNAK | c.11984A>G p.N3995S | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.12); catalogued as COSV57212439; called by muse, mutect2, varscan2
- AHNAK | c.8502G>T p.K2834N | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV57211328; called by muse, mutect2
- AHNAK | c.4646A>G p.D1549G | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.287); catalogued as rs1258340330, COSV57212468; called by muse, mutect2, varscan2
- AHNAK | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV57212491; called by muse, mutect2, varscan2
- AHNAK2 | c.15794C>A p.S5265Y | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60914656, COSV60918416; called by muse, mutect2, varscan2
- AHNAK2 | c.11446T>C p.S3816P | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV60914667; called by muse, mutect2, varscan2
- AHNAK2 | c.6691G>A p.G2231S | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as rs769940659, COSV60914676; called by muse, mutect2, varscan2
- AHNAK2 | c.5150T>C p.V1717A | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as COSV60914682; called by muse, mutect2, varscan2
- AHNAK2 | c.4426G>T p.E1476* | Nonsense Mutation (SNP) | VAF 40/380 reads (11%) | catalogued as COSV100319205; called by muse, varscan2
- AHNAK2 | c.2269C>T p.H757Y | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV60914687; called by muse, mutect2, varscan2
- AIF1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV100559111; called by muse, mutect2
- AIFM1 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.107); catalogued as COSV54854394; called by muse, mutect2, varscan2
- AIFM1 | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54854410; called by muse, mutect2, varscan2
- AIFM1 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | catalogued as COSV54854427; called by muse, mutect2, varscan2
- AIFM2 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771383095, COSV57159167; called by mutect2, varscan2
- AIMP2 | c.683T>G p.V228G | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV52238807; called by muse, mutect2, varscan2
- AIPL1 | c.276+1G>A p.X92_splice | Splice Site (SNP) | VAF 16/68 reads (24%) | catalogued as rs150097891, CS152494; called by muse, mutect2, varscan2
- AIRE | c.553T>C p.S185P | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV52393926; called by muse, mutect2, varscan2
- AK3 | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63346649; called by muse, varscan2
- AK5 | c.1543G>A p.A515T (on ENST00000354567 / NM_174858.3; = p.A489T on NM_012093.4) | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.081); catalogued as rs747870282, COSV100643360, COSV60972063; called by mutect2, varscan2
- AK9 | c.3475C>T p.R1159C | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767239755, COSV58141801; called by muse, mutect2, varscan2
- AK9 | c.953T>G p.L318R | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53421074; called by muse, mutect2, varscan2
- AKAP1 | c.987G>T p.E329D | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV58470113; called by muse, mutect2, varscan2
- AKAP1 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61805573; called by muse, mutect2, varscan2
- AKAP10 | c.1954T>C p.Y652H | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs752426090, COSV56730999; called by muse, mutect2
- AKAP11 | c.730T>C p.S244P | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV50296505; called by mutect2, varscan2
- AKAP11 | c.2477G>T p.R826I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV50296573; called by muse, varscan2
- AKAP11 | c.3779C>T p.A1260V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775366259, COSV50296652; called by muse, mutect2, varscan2
- AKAP11 | c.5391G>T p.E1797D | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as COSV50296708; called by muse, mutect2, varscan2
- AKAP12 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs774124521, COSV53574413; called by muse, mutect2, varscan2
- AKAP12 | c.3568G>A p.E1190K | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771722071, COSV53574426; called by mutect2, varscan2
- AKAP12 | c.3931G>T p.E1311* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV53574447; called by muse, mutect2, varscan2
- AKAP12 | c.4328C>T p.T1443M | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as rs760044084, COSV53574459, COSV99484379; called by muse, mutect2, varscan2
- AKAP13 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as rs756880152, COSV63455994; called by muse, mutect2, varscan2
- AKAP13 | c.3545A>G p.E1182G | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.08); catalogued as COSV63456006; called by muse, mutect2, varscan2
- AKAP13 | c.5446G>T p.D1816Y (on ENST00000394518 / NM_007200.5; = p.D1820Y on NM_006738.6) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63456017; called by muse, mutect2, varscan2
- AKAP13 | c.6874G>A p.A2292T (on ENST00000394518 / NM_007200.5; = p.A2296T on NM_006738.6) | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100774844; called by muse, mutect2, varscan2
- AKAP13 | c.7573G>A p.V2525I (on ENST00000394518 / NM_007200.5; = p.V2529I on NM_006738.6) | Missense Mutation (SNP) | VAF 91/330 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761515628, COSV63456026; called by muse, mutect2, varscan2
- AKAP3 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs773529110, COSV57415683; called by mutect2, varscan2
- AKAP3 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs370794366; called by muse, mutect2, varscan2
- AKAP3 | c.1075A>C p.K359Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57416335; called by muse, mutect2, varscan2
- AKAP3 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV57416352, COSV57420990; called by muse, mutect2, varscan2
- AKAP4 | c.390C>G p.S130R | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV62074342; called by muse, mutect2, varscan2
- AKAP5 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV57742349; called by muse, mutect2, varscan2
- AKAP6 | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV55212724; called by muse, mutect2, varscan2
- AKAP9 | c.3541G>A p.G1181R | Missense Mutation (SNP) | VAF 55/309 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.03); catalogued as COSV62344867; called by muse, mutect2, varscan2
- AKAP9 | c.3907G>T p.E1303* | Nonsense Mutation (SNP) | VAF 54/406 reads (13%) | catalogued as COSV62344883; called by muse, mutect2, varscan2
- AKAP9 | c.4179A>C p.E1393D | Missense Mutation (SNP) | VAF 69/587 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV62344897; called by muse, mutect2, varscan2
- AKAP9 | c.5109G>T p.K1703N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV62344907; called by muse, mutect2
- AKAP9 | c.6849G>T p.E2283D (on ENST00000359028; = p.E2259D on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV62344922; called by muse, mutect2, varscan2
- AKIRIN2 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 20/169 reads (12%) | catalogued as COSV57636465; called by muse, mutect2, varscan2
- AKNA | c.2109G>T p.K703N | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as COSV56312481; called by muse, mutect2, varscan2
- AKNAD1 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs200156438, COSV100645949; called by mutect2, varscan2
- AKNAD1 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV62198085; called by muse, mutect2, varscan2
- AKNAD1 | c.98G>T p.S33I | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as COSV62198099; called by muse, mutect2, varscan2
- AKR1C1 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.92); PolyPhen benign (0.013); catalogued as COSV101080596; called by muse, mutect2
- AKR1C4 | c.713A>G p.D238G | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99578989; called by muse, mutect2
- AKR1D1 | c.439C>A p.L147M | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs973431898, COSV54336058; called by muse, varscan2
- AKR1D1 | c.849T>A p.N283K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54337295; called by muse, mutect2, varscan2
- AKT1 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs113547523, COSV100838393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKT3 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV55609365; called by muse, mutect2, varscan2
- AKT3 | c.630C>A p.S210= | Splice Region (SNP) | VAF 7/33 reads (21%) | catalogued as COSV55615525; called by muse, mutect2, varscan2
- AL031777.2 | c.186G>T p.E62D | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV100587301; called by mutect2, varscan2
- AL049569.3 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 28/105 reads (27%) | PolyPhen possibly damaging (0.833); catalogued as rs375615601; called by muse, mutect2, varscan2
- AL133500.1 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT tolerated, low confidence (0.26); catalogued as rs1310006723, COSV55744332; called by muse, varscan2
- AL133500.1 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 42/372 reads (11%) | SIFT tolerated (0.17); catalogued as COSV99860507; called by muse, varscan2
- AL592490.1 | c.2648C>A p.S883Y | Missense Mutation (SNP) | VAF 77/293 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.172); catalogued as COSV69426126; called by muse, mutect2, varscan2
- AL592490.1 | c.1700G>A p.R567K | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.076); catalogued as rs1020688988, COSV69426135; called by muse, mutect2, varscan2
- AL592490.1 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.162); catalogued as COSV69426143; called by muse, mutect2, varscan2
- AL713999.2 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 30/449 reads (7%) | catalogued as COSV55278423, COSV99826137; called by muse, mutect2
- ALAD | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.204); catalogued as COSV52958792; called by muse, mutect2, varscan2
- ALAS1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs773336919, COSV59626776; called by muse, mutect2, varscan2
- ALB | c.368A>G p.N123S | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV99892456; called by muse, mutect2
- ALDH1A1 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1019486726, COSV52791105; called by muse, mutect2, varscan2
- ALDH1A2 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.174); catalogued as rs1283761840, COSV51078204; called by muse, mutect2, varscan2
- ALDH1A3 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52610132, COSV99439702; called by muse, varscan2
- ALDH1B1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs775731660, COSV66619652, COSV66619678; called by muse, mutect2, varscan2
- ALDH1B1 | c.1520C>T p.T507M | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756415334, COSV66619656; called by muse, mutect2, varscan2
- ALDH1L1 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.523); catalogued as rs749445826, COSV56413656; called by mutect2, varscan2
- ALDH4A1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51892263; called by muse, mutect2, varscan2
- ALDH5A1 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 25/95 reads (26%) | catalogued as COSV62373442, COSV62374719; called by muse, mutect2, varscan2
- ALDH8A1 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.867); catalogued as rs144258828; called by muse, mutect2, varscan2
- ALDOB | c.689A>C p.K230T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as CD156901, COSV66397790; called by muse, varscan2
- ALDOB | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201397971, COSV66397796; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 237/952 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs1349600746, COSV52157533; called by muse, mutect2, varscan2
- ALG1 | c.546G>T p.E182D | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52157541; called by muse, mutect2, varscan2
- ALG10B | c.610A>C p.K204Q | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.109); catalogued as COSV58143137; called by muse, mutect2, varscan2
- ALG11 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV101584401; called by mutect2, varscan2
- ALG12 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 20/145 reads (14%) | PolyPhen benign (0.277); catalogued as rs761301009, COSV58206542; called by muse, mutect2, varscan2
- ALG13 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 57/426 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV52638479; called by muse, mutect2, varscan2
- ALG13 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1057522541, COSV52638497; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG2 | c.1015T>C p.C339R | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV53059715; called by muse, mutect2, varscan2
- ALG2 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.363); catalogued as COSV53059731; called by muse, mutect2, varscan2
- ALG3 | c.1080C>A p.F360L | Missense Mutation (SNP) | VAF 123/438 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs80237396, COSV99891753; called by muse, mutect2, varscan2
- ALG8 | c.897C>T p.I299= | Splice Region (SNP) | VAF 13/65 reads (20%) | catalogued as rs886048686, COSV55200265; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.1178T>G p.I393S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV66566884, COSV66586790; called by muse, mutect2, varscan2
- ALKBH3 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1309421862, COSV57023953; called by muse, mutect2, varscan2
- ALLC | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 49/203 reads (24%) | catalogued as COSV52994406; called by muse, mutect2, varscan2
- ALMS1 | c.5806G>T p.V1936L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV52509070; called by muse, mutect2, varscan2
- ALMS1 | c.11032C>T p.R3678W | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs766771102, COSV52509094; ClinVar: uncertain significance; called by mutect2, varscan2
- ALOX12 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV52349581; called by muse, mutect2, varscan2
- ALOX15 | c.1819G>T p.G607C | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53397574, COSV53398424; called by muse, mutect2, varscan2
- ALOX5 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV65552251; called by muse, mutect2, varscan2
- ALOX5 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs535808410, COSV65552256; called by muse, varscan2
- ALOX5 | c.982C>T p.L328F | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV65552263; called by muse, mutect2, varscan2
- ALOX5 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.367); catalogued as rs368826060, COSV65552210; called by muse, mutect2
- ALPK1 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs377063660, COSV51584702; called by mutect2, varscan2
- ALPK2 | c.5792G>A p.R1931H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1221185165, COSV64492761; called by muse, varscan2
- ALPK3 | c.4178C>T p.A1393V | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV51933045; called by muse, mutect2, varscan2
- ALPP | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1461590076, COSV67396271; called by mutect2, varscan2
- AMBRA1 | c.2225G>A p.R742H (on ENST00000458649 / NM_001367468.1; = p.R652H on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs753438290, COSV54051560; called by mutect2, varscan2
- AMDHD1 | c.492G>T p.E164D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV57138595; called by muse, mutect2, varscan2
- AMER1 | c.2569C>T p.R857* | Nonsense Mutation (SNP) | VAF 8/87 reads (9%) | catalogued as rs1394000391, COSV57662193; called by muse, mutect2
- AMER1 | c.594G>T p.E198D | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.243); catalogued as COSV57660077; called by muse, varscan2
- AMER1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs753930754, COSV57660100; called by muse, varscan2
- AMER2 | c.1690G>A p.G564R | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV63437297; called by muse, varscan2
- AMER3 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1401009215, COSV58465466; called by muse, mutect2
- AMFR | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs376126542; called by muse, mutect2, varscan2
- AMIGO3 | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV57538432; called by muse, mutect2
- AMOTL2 | c.2267G>T p.R756I (on ENST00000422605; = p.R757I on NM_016201.4) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as COSV51438833, COSV51439808; called by muse, mutect2, varscan2
- AMPD1 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 52/402 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745489756, COSV62415980; called by muse, varscan2
- AMPD1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs142123340; called by muse, mutect2, varscan2
- AMPD1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.567); catalogued as rs561023947, COSV62415988; called by mutect2, varscan2
- AMPD2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 66/265 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1255257133, COSV56647663; called by muse, mutect2, varscan2
- AMPH | c.1919A>G p.E640G | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57740927; called by muse, mutect2, varscan2
- AMY2B | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs755109874, COSV100796249, COSV63715171; called by muse, mutect2, varscan2
- AMZ2 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV100703254; called by muse, mutect2
- ANAPC1 | c.4978C>T p.L1660F | Missense Mutation (SNP) | VAF 46/352 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV61975871; called by muse, mutect2, varscan2
- ANAPC15 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56191787; called by muse, mutect2
- ANAPC2 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60569337; called by muse, mutect2, varscan2
- ANAPC4 | c.1250T>G p.F417C | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59543938; called by muse, mutect2, varscan2
- ANAPC5 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 32/132 reads (24%) | catalogued as COSV55842640; called by muse, mutect2, varscan2
- ANGEL2 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as COSV100854008; called by muse, mutect2, varscan2
- ANGPT1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52433501; called by muse, mutect2
- ANGPT1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs777414772, COSV52438978; called by muse, mutect2, varscan2
- ANGPTL1 | c.1274A>C p.K425T | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV99328428; called by muse, mutect2, varscan2
- ANGPTL2 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314178417, COSV52221352; called by muse, mutect2, varscan2
- ANGPTL3 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.556); catalogued as COSV51995482; called by muse, mutect2, varscan2
- ANK1 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV55880544; called by muse, mutect2, varscan2
- ANK2 | c.497C>A p.P166H | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52159404; called by muse, mutect2, varscan2
- ANK2 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 16/144 reads (11%) | catalogued as rs146907003, COSV52159416; called by muse, varscan2
- ANK2 | c.2849G>A p.G950D | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs1437372961, COSV52159428; ClinVar: uncertain significance; called by muse, mutect2
- ANK2 | c.10222C>T p.R3408* | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | catalogued as COSV52159436; called by muse, varscan2
- ANK2 | c.10976G>A p.R3659H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs556640912, CM139925, COSV52159451; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ANK3 | c.9590C>T p.P3197L | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.573); catalogued as COSV55056398; called by muse, mutect2, varscan2
- ANK3 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55056407; called by muse, mutect2, varscan2
- ANKAR | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1559045729, COSV104385776, COSV55612500; called by muse, mutect2, varscan2
- ANKEF1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs150401286; called by muse, varscan2
- ANKFN1 | c.1783-1G>T p.X595_splice | Splice Site (SNP) | VAF 4/25 reads (16%) | catalogued as rs752317555, COSV100594320; called by mutect2, varscan2
- ANKFN1 | c.2204G>A p.G735E | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1365733825, COSV59446632; called by muse, varscan2
- ANKFY1 | c.920T>C p.F307S | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100493267; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6406C>T p.R2136* | Nonsense Mutation (SNP) | VAF 32/116 reads (28%) | catalogued as COSV51846169; called by muse, mutect2, varscan2
- ANKLE2 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs761627940, COSV61709114; called by muse, mutect2, varscan2
- ANKMY1 | c.2815G>T p.E939* | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | catalogued as rs768645991, COSV56033611, COSV56034960; called by muse, mutect2, varscan2
- ANKMY1 | c.2111C>A p.A704D | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV56033628; called by muse, mutect2, varscan2
- ANKMY1 | c.1069-1G>T p.X357_splice | Splice Site (SNP) | VAF 15/40 reads (38%) | catalogued as COSV56033633; called by muse, mutect2, varscan2
- ANKRD11 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs763414376, COSV56360304; called by muse, mutect2, varscan2
- ANKRD13A | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs947717321, COSV55677007; called by muse, mutect2
- ANKRD13A | c.1769A>C p.K590T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99924172; called by muse, mutect2
- ANKRD13B | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67473771; called by muse, mutect2, varscan2
- ANKRD13D | c.*758G>A | Splice Region (SNP) | VAF 10/68 reads (15%) | catalogued as rs772440494, COSV57752222; called by mutect2, varscan2
- ANKRD17 | c.4555G>T p.E1519* | Nonsense Mutation (SNP) | VAF 114/460 reads (25%) | catalogued as COSV100428761, COSV58214758, COSV58219516; called by muse, mutect2, varscan2
- ANKRD17 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.778); catalogued as rs201855956, COSV58219524; called by muse, mutect2, varscan2
- ANKRD23 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV58412553; called by muse, mutect2, varscan2
- ANKRD23 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV58412558; called by mutect2, varscan2
- ANKRD23 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 76/282 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV58412566; called by muse, mutect2, varscan2
- ANKRD26 | c.4873C>T p.L1625F | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.073); catalogued as COSV65775315; called by muse, varscan2
- ANKRD27 | c.2396C>T p.S799L | Missense Mutation (SNP) | VAF 44/365 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.203); catalogued as rs372948651; called by muse, mutect2, varscan2
- ANKRD27 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1230872778, COSV60131364; called by muse, mutect2, varscan2
- ANKRD27 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1306796926, COSV60131372; called by muse, mutect2, varscan2
- ANKRD29 | c.822+2T>C p.X274_splice | Splice Site (SNP) | VAF 37/157 reads (24%) | catalogued as rs1312441098, COSV52425636; called by muse, mutect2, varscan2
- ANKRD30A | c.258G>T p.E86D (on ENST00000611781; = p.E30D on NM_052997.2) | Missense Mutation (SNP) | VAF 52/226 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.222); catalogued as COSV64609453; called by muse, mutect2, varscan2
- ANKRD30A | c.2959G>A p.G987R (on ENST00000611781; = p.G931R on NM_052997.2) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV64606539, COSV64609460; called by muse, mutect2, varscan2
- ANKRD35 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV62910298; called by muse, mutect2, varscan2
- ANKRD42 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as rs780800417, COSV52615647; called by muse, mutect2, varscan2
- ANKRD44 | c.2489G>T p.S830I | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV56554440; called by muse, mutect2, varscan2
- ANKRD45 | c.57A>C p.E19D | Missense Mutation (SNP) | VAF 36/337 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.025); catalogued as COSV60960940; called by muse, mutect2, varscan2
- ANKRD50 | c.2752C>T p.R918W | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs371516395; called by muse, mutect2, varscan2
- ANKRD50 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV72385820; called by muse, mutect2, varscan2
- ANKRD50 | c.1094C>T p.T365I | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV72385502; called by muse, mutect2, varscan2
- ANKRD6 | c.1760G>A p.R587Q (on ENST00000339746 / NM_001242809.2; = p.R582Q on NM_014942.4) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as rs778483690, CM150859, COSV60231051; called by muse, mutect2, varscan2
- ANKS1A | c.2532C>A p.F844L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.78); catalogued as COSV64460410; called by muse, mutect2, varscan2
- ANKS1B | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61349458; called by muse, mutect2, varscan2
- ANKS4B | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV61139151; called by muse, mutect2, varscan2
- ANLN | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV56075806; called by muse, varscan2
- ANO1 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1555047278, COSV60281442; called by muse, mutect2, varscan2
- ANO2 | c.2329G>A p.D777N (on ENST00000356134 / NM_001278597.3; = p.D781N on NM_001278596.3) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372985872; called by muse, mutect2, varscan2
- ANO4 | c.456+2T>C p.X152_splice (on ENST00000392977 / NM_001286615.2; = p.X117_splice on NM_178826.4) | Splice Site (SNP) | VAF 6/21 reads (29%) | catalogued as COSV54594763; called by muse, mutect2, varscan2
- ANO4 | c.649C>A p.P217T (on ENST00000392977 / NM_001286615.2; = p.P182T on NM_178826.4) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54594771; called by muse, varscan2
- ANO4 | c.1378G>T p.D460Y (on ENST00000392977 / NM_001286615.2; = p.D425Y on NM_178826.4) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV54594784; called by muse, mutect2, varscan2
- ANO4 | c.2297A>G p.D766G (on ENST00000392977 / NM_001286615.2; = p.D731G on NM_178826.4) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV100154025; called by muse, mutect2
- ANO5 | c.474T>G p.I158M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.771); catalogued as rs1287869775, COSV61084610; called by muse, mutect2, varscan2
- ANO5 | c.1637C>A p.P546H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV61084618; called by muse, mutect2, varscan2
- ANO6 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV57660610; called by muse, mutect2, varscan2
- ANO7 | c.173G>A p.R58Q (on ENST00000274979; = p.R4Q on NM_001001666.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1381845912, COSV51471322; called by muse, mutect2, varscan2
- ANO7 | c.445C>T p.R149C (on ENST00000274979; = p.R94C on NM_001001666.4) | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs763945681, COSV51467841; called by muse, mutect2, varscan2
- ANO7 | c.1577C>T p.A526V (on ENST00000274979; = p.A472V on NM_001370694.2) | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as rs781293078, COSV51471357; called by muse, varscan2
- ANO9 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs377737999; called by muse, mutect2, varscan2
- ANOS1 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.301); catalogued as rs1460369434, COSV52919159; called by muse, mutect2, varscan2
- ANP32E | c.35G>A p.R12K | Missense Mutation (SNP) | VAF 213/851 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV58482045; called by muse, mutect2, varscan2
- ANXA13 | c.876G>T p.Q292H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.837); catalogued as rs745692488, COSV51623072; called by muse, mutect2, varscan2
- ANXA4 | c.19G>T p.G7* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV67848764; called by muse, mutect2, varscan2
- ANXA4 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs765123505, COSV67848767; called by muse, mutect2, varscan2
- ANXA6 | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62906634; called by muse, mutect2, varscan2
- ANXA9 | c.970C>A p.L324I | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV100385724; called by muse, mutect2, varscan2
- AOC1 | c.1949T>C p.F650S | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62868451; called by muse, mutect2, varscan2
- AOC3 | c.1269G>T p.K423N | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.267); catalogued as COSV53826314; called by muse, mutect2, varscan2
- AOX1 | c.1625A>G p.Y542C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV65981447; called by muse, mutect2, varscan2
- AP002748.5 | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.11); catalogued as COSV100568227; called by muse, mutect2, varscan2
- AP1AR | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV56769037; called by muse, mutect2, varscan2
- AP1G1 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as rs1254154362, COSV55488869; called by muse, mutect2, varscan2
- AP2A1 | c.1708C>T p.R570C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as rs1023243851, COSV100756540; called by muse, mutect2
- AP2A2 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV59960158; called by muse, varscan2
- AP3B1 | c.3259C>A p.L1087M | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54882982; called by muse, varscan2
- AP3B2 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.179); catalogued as COSV55609302, COSV99916604; called by muse, varscan2
- AP3D1 | c.2132T>C p.V711A | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV61427770; called by muse, mutect2, varscan2
- AP3D1 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as rs747599851, COSV61426442; called by muse, mutect2, varscan2
- AP3M1 | c.652C>A p.L218I | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV62331259; called by muse, mutect2, varscan2
- AP3M2 | c.263A>C p.D88A | Missense Mutation (SNP) | VAF 77/377 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.159); catalogued as COSV51528570; called by muse, mutect2, varscan2
- AP3S2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs148740750; called by muse, mutect2
- AP3S2 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372598574; called by muse, mutect2, varscan2
- AP4E1 | c.2761G>A p.V921I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV55916820; called by muse, varscan2
- AP5B1 | c.2279T>C p.F760S | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV57502867; called by muse, mutect2, varscan2
- AP5Z1 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as rs765200689, COSV62240958; called by muse, mutect2, varscan2
- APBA1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762371853, COSV55227236; called by mutect2, varscan2
- APBA2 | c.977G>T p.R326M | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV67104673; called by muse, mutect2, varscan2
- APBA2 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as rs142481200; called by mutect2, varscan2
- APBB1 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as rs375733189; called by muse, mutect2, varscan2
- APBB1IP | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.82); catalogued as COSV63302440; called by muse, mutect2, varscan2
- APBB1IP | c.326C>A p.S109Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV63302445; called by muse, mutect2, varscan2
- APC | c.6757C>A p.L2253I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV57342027, COSV99967229; called by muse, mutect2, varscan2
- APC | c.7202T>C p.L2401P | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.961); catalogued as COSV57342036; called by muse, mutect2, varscan2
- APC | c.7573C>T p.R2525C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774952444, COSV57342043; ClinVar: uncertain significance; called by mutect2, varscan2
- APC2 | c.5291G>A p.S1764N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as rs771184037, COSV99279960; called by mutect2, varscan2
- APEH | c.1493C>T p.T498I | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV56533537; called by muse, mutect2, varscan2
- APH1B | c.463T>C p.F155L | Missense Mutation (SNP) | VAF 84/321 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV56014284; called by muse, mutect2, varscan2
- API5 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66633134; called by muse, mutect2, varscan2
- APLNR | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 27/116 reads (23%) | catalogued as COSV57242507, COSV57243448; called by muse, mutect2, varscan2
- APLP1 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs777735772, COSV55703144; called by muse, mutect2, varscan2
- APMAP | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV54173037; called by muse, varscan2
- APMAP | c.110G>T p.R37I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV99469173; called by muse, varscan2
- APOA2 | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.093); catalogued as COSV57154834; called by muse, mutect2, varscan2
- APOA5 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV57063080; called by muse, mutect2, varscan2
- APOB | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV51934161; called by muse, mutect2, varscan2
- APOB | c.863T>G p.L288R | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51934173; called by muse, mutect2
- APOBEC1 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 45/473 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs778220694, COSV57549299; called by muse, mutect2
- APOBEC3B | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs747498277, COSV59840889; called by muse, varscan2
- APOBEC3B | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as rs1411068983, COSV59840898; called by muse, varscan2
- APOBEC3C | c.491A>G p.D164G | Missense Mutation (SNP) | VAF 74/368 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs1443405528, COSV53326513; called by muse, varscan2
- APOBEC3F | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs543621665, COSV57910638; called by muse, mutect2, varscan2
- APOBEC3H | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs369920603; called by muse, mutect2
- APOC1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs369438021, COSV52991492; called by muse, mutect2, varscan2
- APOL3 | c.1075G>A p.E359K (on ENST00000349314 / NM_145640.2; = p.E288K on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs542353913, COSV62579670; called by mutect2, varscan2
- APOL3 | c.323G>T p.R108I (on ENST00000349314 / NM_145640.2; = p.R37I on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as COSV62579681; called by muse, mutect2, varscan2
- APOL5 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as rs772110138, COSV50766844; called by mutect2, varscan2
- APOL5 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs763219644, COSV50766586; called by mutect2, varscan2
- APOL6 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371590566, COSV68749458; called by muse, mutect2, varscan2
- APOOL | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64271606; called by muse, varscan2
- APOOL | c.800G>T p.R267I | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV60576489; called by muse, mutect2, varscan2
- APP | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1341026713, COSV60998063; called by muse, mutect2, varscan2
- APP | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201102339, COSV61006980; called by muse, mutect2
- APPL1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.568); catalogued as rs753038546, COSV55700704; called by muse, mutect2, varscan2
- APPL1 | c.762G>T p.L254F | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV55700712; called by muse, mutect2
- APPL2 | c.1739T>C p.I580T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV51590103; called by muse, mutect2, varscan2
- AQP11 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320262703, COSV57992399; called by muse, mutect2, varscan2
- AQP2 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as CM056523, COSV52230047; called by muse, mutect2, varscan2
- AQP2 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs150344189; called by muse, mutect2, varscan2
- AQP6 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs766657221, COSV59646258; called by muse, varscan2
- AQR | c.2650G>T p.E884* | Nonsense Mutation (SNP) | VAF 16/146 reads (11%) | catalogued as COSV99334866; called by muse, mutect2, varscan2
- AQR | c.2221G>A p.A741T | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV50031348, COSV50033409; called by muse, mutect2, varscan2
- AQR | c.1941G>T p.E647D | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV50033454; called by muse, mutect2, varscan2
- AQR | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as rs774986360, COSV50033490; called by muse, mutect2, varscan2
- AR | c.1517G>A p.G506D | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1403123525, COSV101019719; called by muse, mutect2
- ARAF | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV51692445; called by muse, mutect2, varscan2
- ARAP2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs199740529, COSV58285033; called by muse, mutect2, varscan2
- AREL1 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs746270046, COSV62666333; called by mutect2, varscan2
- ARF1 | c.107A>C p.K36T | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as COSV55254756; called by muse, mutect2, varscan2
- ARFGAP2 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as rs1413666492, COSV53565507; called by muse, mutect2, varscan2
- ARFGAP2 | c.444G>T p.E148D | Missense Mutation (SNP) | VAF 26/506 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV100096701; called by muse, mutect2
- ARFGAP3 | c.602A>G p.N201S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54311783; called by muse, mutect2, varscan2
- ARFGEF1 | c.5311G>A p.E1771K | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV51583998; called by muse, mutect2, varscan2
- ARFGEF1 | c.3319G>A p.A1107T | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99145407; called by muse, mutect2
- ARFGEF1 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs764719716, COSV51607682; called by muse, mutect2, varscan2
- ARFGEF1 | c.459+2T>C p.X153_splice | Splice Site (SNP) | VAF 8/94 reads (9%) | catalogued as COSV99145418; called by muse, mutect2
- ARFGEF2 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1022300649, COSV64211590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARFGEF2 | c.2139C>G p.D713E | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64212061; called by muse, mutect2, varscan2
- ARFGEF2 | c.3884G>A p.R1295H | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150273470, COSV64212065; called by muse, varscan2
- ARFGEF2 | c.4640C>T p.A1547V | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.206); catalogued as rs1263401370, COSV100904535; called by muse, mutect2
14,132 further variants in this file (10,289 protein-altering or splice-affecting, 3,546 silent, 297 other) are not listed here.
